CPTAC case C3L-08633 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/97b41ddc-6f1c-444f-88c9-69a3473f6f2f

Demographics
Sex at birth: male; Race: white; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 258 days; Progression or recurrence: no; Days to last follow up: 258 days; Clark level: IV; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.3 cm; Margin status: Indeterminate.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 238 days; Disease response: Tumor Free.
- Days to follow up: 258 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-08633-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -20 days; Initial weight: 127 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08633-21: Section location: Extremities; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-08633-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -20 days; Method of sample procurement: Blood Draw.
